RC case RC-B65B — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3b02ae7b-b0de-4574-b84f-d45e44002c60

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1931; Vital status: Dead; Days to death: 290 days; Year of death: 2011; Cause of death: Cancer Related.

Diagnoses (3)
1. Angioimmunoblastic T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9705/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 79.7 years (29,093 days); Year of diagnosis: 2011; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: No; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: Yes; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): High Risk; Sites of involvement: Lymph Node, Axillary / Lymph Node, Hilar / Lymph Node, Iliac-Common / Lymph Node, Inguinal / Lymph Node, Mediastinal / Lymph Node, Para-Aortic / Bone, NOS / Bone marrow / Peripheral blood / Skin / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Etoposide + Prednisone; Initial disease status: Initial Diagnosis; Regimen or line of therapy: CEP; Days to treatment start: 249 days; Days to treatment end: 278 days; Reason treatment ended: Death; Timepoint category: First Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Prior malignancy of the prostate gland (histology not recorded by GDC). Age at diagnosis: 65.5 years (23,910 days); Year of diagnosis: 1997; Days to diagnosis: -5,183 days (-14.2 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -5,183 days (-14.2 years); Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS.
3. Progression (histology not recorded by GDC). Age at diagnosis: 80.3 years (29,334 days); Days to diagnosis: 241 days.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Day 241 (progression): Progression or recurrence: Yes; Days to progression: 241 days.
- Day 290 (end of treatment course 1): Disease response: With Tumor.

Molecular and laboratory tests
- Lactate Dehydrogenase 269 U/L [Blood test normal range upper: 246].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Atrial Fibrillation / Coronary Artery Disease / Hyperlipidemia.
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash.
- Timepoint category: Initial Diagnosis; Weight: 92 kg; Height: 175 cm; BMI: 30.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Head and Neck Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Liver Cancer.

Biospecimens (2 samples)
- Sample RC-B65B-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B65B-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
